Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YN, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YN-01A (Primary Tumor).

[page 1 of 4]
Patient: [REDACTED]

Surgical Pathology: Additional Information: [REDACTED] Accession: [REDACTED]

Surg Path

CLINICAL HISTORY:

Brain tumor. Brain neoplasm NOS. HISTORY OF PRESENT ILLNESS: This is a year-old female with a history of breast cancer status post bilateral mastectomies, hypertension, GERD who presented with complaints of visual and olfactory seizures, headache and right temporal well-differentiated astrocytoma status post brain biopsy and is being electively admitted for craniotomy and tumor resection

GROSS EXAMINATION:

A. "Brain tissue", received fresh for frozen section and placed in formalin at on [REDACTED] is a 3.5 x 2.1 x 1.3 cm piece of tissue, representative sections frozen and submitted in AF1 (some tissue taken by tissue bank). Tissue from block AF1 is placed entirely in block A1 the remaining tissue is submitted in block A2-3.

B. "Brain tissue", received fresh and placed in formalin at on [REDACTED] are multiple pieces of pink-white soft tissue consistent with brain (4 x 3 x 1.3 cm in aggregate) which are submitted entirely in blocks B1-3.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1 (rep)- glioma, low grade

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain diffusely infiltrated by an astrocytic neoplasm. Endothelial proliferation and necrosis are not seen. There are some gemistocytes and a brisk perivascular and leptomeningeal lymphocytic infiltrate. Astrocytes are immunopositive for GFAP. HAM-56 and LCA highlight inflammatory cells and microglia. The MIB-1 index is approximately 10%.

IMMUNOHISTOCHEMICAL FINDINGS:

The immunoperoxidase tests reported herein were developed and their performance characteristics were determined by the

Some of them may not be cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing.

DIAGNOSIS:

A. BRAIN TISSUE, CRANIOTOMY:

ANAPLASTIC ASTROCYTOMA (WHO GRADE III).

B. BRAIN TISSUE, CRANIOTOMY:

ANAPLASTIC ASTROCYTOMA (WHO GRADE III).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

ICD-O-3

Astrocytoma, grade III 9401/3
Site: Brain, supratentorial NOS C71.0
path: Brain, NOS C71.9
W 5/5/14

[page 2 of 4]
Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

FISH MARKER	INTERPRETATION	% OF TUMOR CELLS EXHIBITING ABNORMALITY	FINDINGS/STATUS
EGFR (7p12)	ABNORMAL	52%	GAIN
MET (7q31)	ABNORMAL	48%	GAIN
7 CEP	ABNORMAL	45%	GAIN
PTEN (10q23)	NORMAL		INTACT
10 CEP	NORMAL		INTACT
CDKN2A (9p21)			NOT ORDERED
9 CEP			NOT ORDERED
1p36			NOT ORDERED
1q25			
1p32			NOT ORDERED
1qtet			
19q13			NOT ORDERED
19p13			

EGFR, 7 CEP, PTEN, AND 10 CEP: 2 OF 4 ABNORMAL MARKERS.
MET EXHIBITS GAIN.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF PATIENTS WITH ANAPLASTIC ASTROCYTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH >2 MARKERS (P=0.037) EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

ADDENDUM 2:

BRAIN TISSUE CONTAINING ANAPLASTIC ASTROCYTOMA (WHO GRADE III; [REDACTED] BLOCK A2).

IHC Antibody:	Interpretation IHC	Score (0-3+)	% of Tumor Cells of Exhibiting Staining	ACIS III SCORE
CD/45-LCA			10%	
Ki-67	HIGH		10% IN SURG PATH	
MGMT	POSITIVE		20%	20%
EGFR WT	POSITIVE	2+	80%	
EGFR VIII	NEGATIVE		0%	0%
PTEN	NOT ORDERED			
pS6	POSITIVE	2+	25%	

[page 3 of 4]
PAKT	NEGATIVE	1+	90%
pMAPK	NEGATIVE	2+	5%
CA-IX	NEGATIVE		0%
VEGF	POSITIVE	2+	60% = 120
PDGFr Alpha	WIDESPREAD		60%
PDGFr Beta	WIDESPREAD		80%
VEGFr-KDR	NEGATIVE	2+	5% = 10
HIF2 Alpha:	NOT ORDERED		

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

ADDENDUM 3:
MGMT PROMOTER METHYLATION REAL TIME PCR ANALYSIS

Received [REDACTED] from [REDACTED]
is a copy of an MGMT Promoter Methylation Assay, obtained at the request of Dr. [REDACTED] on paraffin block [REDACTED]. The complete report from [REDACTED] is on file in the [REDACTED].

Result:

MGMT PROMOTER METHYLATION IDENTIFIED

Methodology:

DNA is isolated from formalin-fixed, paraffin-embedded (FFPE) specimen. Molecular analysis of the MGMT gene is performed by methylation-specific PCR. Molecular-based testing is highly accurate but as in any laboratory test, rare diagnostic errors may occur.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

ADDENDUM 4:

Please see MOLECULAR DIAGNOSTICS Report [REDACTED] for complete report.

Testing was performed on sample [REDACTED] BLOCK A2.

IDH1 MUTATION TESTING WITH REFLEX TO IDH2

INTERPRETATION: NEGATIVE

IDH1 AND IDH2 MUTATIONS NOT DETECTED

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

[page 4 of 4]
Electronically signed: [REDACTED]

ADDENDUM 5:

EGFR VIII IMMUNOHISTOCHEMISTRY: NEGATIVE

None of the tumor cells exhibit staining for EGFR VIII (Score = 0).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]
Performed by: SURGICAL PATHOLOGY

Ordering MD:

Criteria	hw 10/4/13	Yes	No
Prior Malignancy History	breast	✓	✓

Printed by: [REDACTED]

Source: NCI Genomic Data Commons file 9799eb52-5e43-4465-8dc5-d3c279a2485e (TCGA-E1-A7YN.2C9A41BE-767B-4929-9186-E7821015AC42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).